Gene-level copy-number profile of tumor specimen AP-6EWG-XT from APOLLO case AP-6EWG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-6EWG-XT: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4f5f59a6-b91a-44a1-8664-91f42fbd6dba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-6EWG-SS (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/0e611c9a-9fcf-43ba-8ba7-096e7874cb06

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 566; copy number 1: 8,300; copy number 2: 29,751; copy number 3: 15,703; copy number 4: 4,458; copy number 5: 124; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,760,919–57,031,158, 11 genes (within-gene range 0–1): AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P.
- chr10:38,601,418–38,783,108, 8 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:48,880,111–48,951,895, 5 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP.
- chr12:2,877,223–2,941,138, 1 gene (within-gene range 0–2): TULP3.
- chr12:2,954,240–3,044,950, 3 genes: RNU6-1315P, TEAD4, AC125807.2.
- chr12:14,169,746–14,365,503, 7 genes: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11.
- chr13:49,620,314–49,936,490, 9 genes: AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7.
- chr18:45,788,530–46,128,333, 10 genes: AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 126 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:122,909,082–123,028,605, 1 gene, copy number 5 (within-gene range 3–5): SEMA5B.
- chr3:138,482,065–138,485,755, 1 gene, copy number 5: AC022497.1.
- chr3:169,483,671–169,484,080, 1 gene, copy number 5 (within-gene range 4–5): RPL22P1.
- chr3:171,058,414–171,460,408, 1 gene, copy number 5 (within-gene range 3–5): TNIK.
- chr3:171,439,526–172,401,669, 14 genes, copy number 5: Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1.
- chr3:185,076,838–190,892,429, 104 genes, copy number 5–6 (broad region; genes not listed).
- chr6:25,023,247–25,057,073, 4 genes, copy number 5 (within-gene range 3–5): ASS1P1, RN7SL334P, AL133268.3, AL133268.2.

Autosomal genes at a single copy (total copy number 1): 8,294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
